Gene-level copy-number profile of tumor specimen ALCH-B01I-TTP1-A from ALCHEMIST case ALCH-B01I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 64.4 years (23,537 days).
Specimen ALCH-B01I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1609f39f-e297-4d58-8a91-b7151634be41.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B01I-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/10285cd6-4090-45b5-b70c-409e946c4562

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 3,093; copy number 2: 55,292; copy number 3: 526.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:50,155,045–50,189,075, 2 genes (within-gene range 0–2): SEMA3F, AC104450.1.
- chr4:182,881,777–182,882,203, 1 gene: AC079766.1.
- chr13:112,056,845–112,108,015, 3 genes (within-gene range 0–1): SOX1-OT, SOX1, AL356961.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 237. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
